Surgical pathology report (de-identified scan), TCGA case TCGA-NH-A8F7, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Candler, specimen TCGA-NH-A8F7-01A (Primary Tumor).

[page 1 of 4]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

Lab Database:

PATIENT: [REDACTED] ACCT #: [REDACTED] LOC: [REDACTED]
AGE/SX: [REDACTED] F ROOM: [REDACTED]
REG DR: [REDACTED] DOB: [REDACTED] BED: [REDACTED]
STATUS: [REDACTED]

SPEC #: [REDACTED] RECD: [REDACTED] STATUS: [REDACTED] PERFORMED AT [REDACTED]
COLL: [REDACTED] TIME IN FORMALIN: [REDACTED] hrs.
COLD ISCHEMIA TIME: [REDACTED] mins.

CLINICAL INFORMATION:

Pre-Op Diagnosis:

Remarks:

Specimen(s): A. Subtotal colectomy with left tube and ovary
B. Right tube and ovary

*Adenocarcinoma NOS 8146/3
Site: Sigmoid colon C18.7
pN 4/12/14*

MICROSCOPIC DIAGNOSIS

A. COLON, TERMINAL ILEUM, APPENDIX AND OMENTUM (SUBTOTAL COLECTOMY):

TUMOR #1

- MODERATELY DIFFERENTIATED ADENOCARCINOMA OF CECUM
- TUMOR INVADES THROUGH THE BOWEL WALL
- METASTATIC CARCINOMA IN 8 OF 23 REGIONAL LYMPH NODES
- METASTATIC CARCINOMA TO OMENTUM
- MARGINS APPEAR UNINVOLVED WITH CLOSEST MARGIN RADIAL. <1 CM TO METASTATIC CARCINOMA

TUMOR #2

- MODERATELY DIFFERENTIATED ADENOCARCINOMA, SIGMOID COLON
- TUMOR INVADES FOCALLY THROUGH THE BOWEL WALL *collected*
- NO METASTASIS IN 18 REGIONAL LYMPH NODES
- MARGINS APPEAR UNINVOLVED WITH CLOSEST MARGIN DISTAL AT 5 CM FROM TUMOR

LEFT FALLOPIAN TUBE AND OVARY (SALPINGO-OOPHORECTOMY) *Specimen*

- METASTATIC ADENOCARCINOMA TO OVARY *- collected from ovary*

B. RIGHT FALLOPIAN TUBE AND OVARY (SALPINGO-OOPHORECTOMY):

- METASTATIC ADENOCARCINOMA TO FIMBRIATED END OF FALLOPIAN TUBE

COMMENT(S)

The subtotal colectomy contained two separate but histologically indistinguishable, moderately differentiated adenocarcinomas. Tumor #1 was located in the cecum and appeared more advanced with numerous metastasis to regional lymph nodes. Tumor #2 was located in the sigmoid colon without regional lymph node metastasis. In completing the synoptic reports below, I judged the metastatic tumor to be associated with the more advanced cecal adenocarcinoma.

** CONTINUED ON NEXT PAGE **

[page 2 of 4]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry
Lab Database:

PAGE 2

SPEC #

PATIENT:

(Continued)

COMMENT(S)

(Continued)

SURGICAL PATHOLOGY CANCER CASE SUMMARY (CECAL TUMOR) - CAP APPROVED

Specimen: Terminal ileum, cecum, appendix, ascending colon,
transverse colon, descending colon, sigmoid colon,
bilateral ovaries and fallopian tubes, omentum

Procedures: Subtotal colectomy with BSO

CECAL TUMOR:

Tumor Site: Cecum
Tumor Size: 4.5 cm in greatest dimensions
Macroscopic Tumor Perforation: Not identified
Histologic Type: Adenocarcinoma
Histologic Grade: Low-grade
Microscopic Tumor Extension: Tumor invades through the muscularis propria into the
subserosal adipose tissue or the nonperitonealized
pericolic or perirectal soft tissues but does not extend
to the serosal surface

Margins: Proximal, distal and radial margins appear uninvolved
with metastatic tumor within 1 cm of radial margin at
ileocecal junction

Treatment Effect: No prior treatment
Lymph-Vascular Invasion: Present
Perineural Invasion: Not identified
Tumor Deposits: Present
Pathologic Staging: Primary Tumor: pT3
Regional Lymph Nodes: pN2b
Number examined: 23
Number involved: 8
Distant Metastasis: pM1b - metastasis to left
ovary, right fallopian tube and omentum

SIGMOID TUMOR

Tumor Site: Sigmoid colon
Tumor Size: 5.5 cm in greatest dimensions
Macroscopic Tumor Perforation: Not identified
Histologic Type: Adenocarcinoma
Histologic Grade: Low-grade
Microscopic Tumor Extension: Tumor invades through the muscularis propria into the
subserosal adipose tissue or the nonperitonealized
pericolic or perirectal soft tissues but does not extend
to the serosal surface

Margins: Proximal, distal and radial margins appear uninvolved
with metastatic tumor within 5 cm from distal margin

Treatment Effect: No prior treatment
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Tumor Deposits: Not identified
Pathologic Staging: Primary Tumor: pT3

** CONTINUED ON NEXT PAGE **

[page 3 of 4]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry
Lab Database:

PAGE 3

SPEC #:

PATIENT:

(Continued)

COMMENT(S)

(Continued)

Regional Lymph Nodes: pN0
Number examined: 18
Number involved: 0
Distant Metastasis: not applicable

GROSS DESCRIPTION:

Specimen A is received in the fresh state labeled "subtotal colectomy with left tube and ovary". The specimen consists of the following:

- 15 cm of terminal ileum measuring 2 cm in diameter
- Vermiform appendix measuring 5 cm in length by 0.7 cm in diameter
- 65 cm of large intestine measuring approximately 5 cm in diameter
- Attached omentum measuring 20 x 14 by up to 2 cm in thickness
- An ovary and fallopian tube attached in the area of the sigmoid colon
- Mesentery measuring up to 9 cm in radial dimension at the ileocecal junction and up to 9 cm in radial dimension at the sigmoid colon

Adhesions are noted at the ileocecal junction and between the ovary and sigmoid colon. There are firm tumorous nodules in the mesentery at the ileocecal junction and in the omentum. The omental tumor nodule measures 2 cm in greatest dimension. There are multiple mesenteric nodules at the ileocecal junction measuring up to 1.5 cm in greatest dimension. The bowel is opened to reveal a circumferential fungating tumor in the cecum approximately 2 cm from the ileocecal valve. This tumor measures 4.5 cm along the length of the bowel. The bowel is narrowed in this area. A second circumferential fungating mucosal tumor is identified 5 cm above the distal margin. This second tumor measures 5.5 cm along the length of the bowel and again the bowel appears narrowed in this area. The attached ovary appears enlarged, measuring 5 x 4.5 x 3 cm. It has a smooth tan surface. Its cut surface reveals soft tan tumorous tissue replacing 90% of the ovary. The fallopian tube with fimbriated end measures 4.5 cm in length by 0.5 cm in diameter. The initial gross features are reported to Dr. [redacted] in the O.R. at [redacted]. The specimen is allowed to fix overnight prior to sectioning. Representative sections are submitted as follows:

- A1 - terminal ileum
- A2 - vermiform appendix
- A3-6 - cecal tumor
- A7-12 - lymph nodes in mesentery regional to cecal tumor
- A13 - apex of ileocecal mesentery
- A14 - omental tumor nodule
- A15,16 - left ovary and tube
- A17-20 - distal tumor
- A21 - distal margin
- A22-25 - lymph nodes and mesentery regional to distal tumor

NOTE: The tumors invade the full thickness of the bowel wall, likely extending through the bowel wall.

Specimen B is received in formalin labeled "right tube and ovary" This is an ovary with

** CONTINUED ON NEXT PAGE **

[page 4 of 4]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry
Lab Database:

PAGE 4

SPEC #: PATIENT: (Continued)

GROSS DESCRIPTION: (Continued)

attached fallopian tube. The tube with fimbriated end measures 4.5 cm in length by 0.5 cm in diameter. The ovary measures 3.5 x 1.2 x 1 cm. It has a normal appearing wrinkled tan surface. The tube is unremarkable. The ovary has a solid tan to white cut surface without obvious tumor. Representative sections are submitted in cassettes B1 and B2.

INTRAOPERATIVE CONSULTATION:

SUBTOTAL COLECTOMY, GROSS EXAM:

- TWO SEPARATE COLON CANCERS IDENTIFIED, ONE IN THE CECUM AND THE OTHER 5 CM ABOVE THE DISTAL MARGIN
- MARGINS APPEAR UNINVOLVED
- FINDINGS REPORTED TO DR. IN THE O.R. AT
- TUMOR HARVESTED FOR TISSUE BANKING

PHOTO DOCUMENTATION

Image

Signed (signature on file)

** END OF REPORT **

Source: NCI Genomic Data Commons file 7245cede-7ed9-47c5-8571-8c99197feb08 (TCGA-NH-A8F7.4D9A2D24-529F-4CFE-8444-013FAAF696EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).